Somatic mutation profile of tumor specimen MMRF_1838_1_BM_CD138pos (aliquot MMRF_1838_1_BM_CD138pos_T1_KBS5U_L07285) from MMRF case MMRF_1838, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.7 years (26,537 days).
Specimen MMRF_1838_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 798ec287-b06e-41f6-8bb3-1c32e8c99beb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1838_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1838_1_PB_Whole_C2_KBS5U_L07286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c748ddf-3177-4678-9756-855afa21c464

The open-access MAF lists 57 somatic variants for this specimen: 22 protein-altering or splice-affecting, 9 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 17, Silent 9, Intron 5, 3'Flank 3, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 45/125 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.1192C>T p.P398S (on ENST00000392977 / NM_001286615.2; = p.P363S on NM_178826.4) | Missense Mutation (SNP) | VAF 71/142 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54585932; called by muse, mutect2, varscan2
- KCTD16 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868542964, COSV72579641; called by muse, mutect2, varscan2
- KLF7 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs536720710, COSV100519156; called by muse, mutect2, varscan2
- NEUROD4 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 62/115 reads (54%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV54473321; called by muse, mutect2, varscan2
- NLGN2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753026024; called by muse, mutect2, varscan2
- NSFL1C | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1193514014; called by muse, mutect2, varscan2
- OR2T34 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100170301, COSV60899697; called by muse, mutect2
- PUF60 | c.898G>A p.G300S (on ENST00000526683 / NM_001362896.2; = p.G283S on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV57587000; called by muse, mutect2
- ZEB2 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV57958275; called by muse, mutect2, varscan2
- ZNF805 | c.953_954del p.K318Rfs*9 | Frame Shift Del (DEL) | VAF 52/152 reads (34%) | catalogued as rs1290681275; called by mutect2, pindel, varscan2
- ARFGEF2 | c.2825A>T p.D942V | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C22orf23 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EMCN | c.396T>G p.I132M | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- GRAMD1A | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2
- HEPH | c.3209G>T p.S1070I (on ENST00000343002; = p.S803I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- IQCE | c.1978C>G p.P660A | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF5C | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 48/204 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OGT | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); called by muse, mutect2
- OSBPL6 | c.1445A>T p.N482I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PTPRA | c.1869G>T p.E623D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SGPP1 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- CRACDL | c.1872C>T p.H624= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- CYP4F3 | c.915C>T p.S305= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as rs1426856546; called by muse, mutect2, varscan2
- HECW1 | c.1734G>A p.A578= | Silent (SNP) | VAF 54/132 reads (41%) | catalogued as COSV67840222; called by muse, mutect2, varscan2
- IGHV5-51 | c.298C>T p.L100= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as rs183770636; called by muse, mutect2
- MYH14 | c.2655G>A p.Q885= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1261380486; called by muse, mutect2, varscan2
- MYL1 | c.582C>T p.I194= | Silent (SNP) | VAF 193/442 reads (44%) | called by muse, mutect2, varscan2
- MYO16 | c.282G>T p.G94= | Silent (SNP) | VAF 67/141 reads (48%) | catalogued as rs769013062; called by muse, mutect2, varscan2
- SLC2A13 | c.1533G>A p.L511= | Silent (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- WRN | c.1236A>G p.E412= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs746496708; called by muse, mutect2, varscan2
- ATAD2B | c.*420del | 3'UTR (DEL) | VAF 36/72 reads (50%) | catalogued as rs924998091; called by mutect2, varscan2
- BET1L | c.*1998C>T | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- C6orf118 | c.*373A>C | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949913 T>A | 3'Flank (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
- CASK | c.*304A>G | 3'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CDC42SE1 | chr1:151050976 G>A | 3'Flank (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.*929C>T | 3'UTR (SNP) | VAF 7/68 reads (10%) | catalogued as rs1006109555, COSV70501422; called by muse, varscan2
- COL21A1 | c.*701C>T | 3'UTR (SNP) | VAF 62/125 reads (50%) | called by muse, mutect2, varscan2
- CTDSP1 | c.*910C>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs1559139740; called by muse, mutect2, varscan2
- DST | c.21609+52T>G | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2, varscan2
- FAM98B | c.*279G>C | 3'UTR (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1161+56C>G | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as rs1376101608; called by muse, mutect2, varscan2
- HIPK1 | c.*993del | 3'UTR (DEL) | VAF 40/84 reads (48%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.*444C>T | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
- KLF2 | c.-72C>G | 5'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- LCK | c.*222G>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- MARCHF6 | c.973-173G>C | Intron (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- PGBD5 | chr1:230321682 G>A | 3'Flank (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- QKI | c.1009+805G>T | Intron (SNP) | VAF 70/126 reads (56%) | called by muse, mutect2, varscan2
- RAX | c.*157G>A | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RBM20 | c.*577G>A | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- SEMG1 | c.*35C>T | 3'UTR (SNP) | VAF 153/388 reads (39%) | called by muse, mutect2, varscan2
- TEPSIN | c.527-431G>A | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as rs966499190; called by muse, mutect2, varscan2
- USP25 | c.*13C>T | 3'UTR (SNP) | VAF 235/566 reads (42%) | called by muse, mutect2, varscan2
- USP38 | c.*604G>A | 3'UTR (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2, varscan2
- ZBED3 | c.*2020C>T | 3'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
